HCMI case HCM-BROD-0690-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/427b401b-b73a-450d-ad99-028033c6aa54

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1970; Vital status: Dead; Days to death: 2,424 days (6.6 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 33.9 years (12,381 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T3b; AJCC pathologic N: NX; AJCC pathologic M: M1c; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Small intestine.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Ipilimumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,331 days (6.4 years); Days to treatment end: 2,397 days (6.6 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C79.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Small intestine, NOS; Classification of tumor: metastasis; Age at diagnosis: 33.9 years (12,381 days); Satellite nodule present: Indeterminate.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Lymph nodes positive: 0; Lymph nodes tested: 0.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Temozolomide; Treatment intent type: Maintenance Therapy; Days to treatment start: 1,973 days (5.4 years); Days to treatment end: 2,219 days (6.1 years).

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Small intestine, NOS; Days to progression: 0 days.
- Days to follow up: 2,424 days (6.6 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 185 cm; BMI: 21.3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-0690-C43-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 6.
